Surgical pathology report (de-identified scan), TCGA case TCGA-RM-A68T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RM-A68T-01A (Primary Tumor).

Microscopic Discussion:

Sections demonstrate a paraganglioma characterized by a proliferation of monotonous cells with round nuclei and salt and pepper chromatin, prominent red nucleoli and eosinophilic cytoplasm. These cells are arranged in small nests surrounded by a delicate capillary network. One mitotic figure per 10 high-power fields is identified. Bands of fibroelastic tissue intersect the tumor cells. Few entrapped nerve fibers are also seen. Necrosis is not identified.

Diagnosis:

Neck Tumor- Paraganglioma

Prior Discrepancy History		

Source: NCI Genomic Data Commons file 260197e1-822c-4ccf-b809-96d11da5db6a (TCGA-RM-A68T.49F14C96-CA57-469E-9615-FED1F902ED95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).